Somatic mutation profile of tumor specimen TCGA-AO-A0J3-01A (aliquot TCGA-AO-A0J3-01A-11W-A050-09) from TCGA case TCGA-AO-A0J3, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 67.1 years (24,519 days).
Specimen TCGA-AO-A0J3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58498ed9-ca2c-4e24-8487-a8387e8fee50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0J3-10A (Blood Derived Normal), aliquot TCGA-AO-A0J3-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/945ea90d-d675-4665-a105-4662dd4766cf

The open-access MAF lists 88 somatic variants for this specimen: 64 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 21, Nonsense Mutation 5, Frame Shift Del 3, 3'UTR 2, Splice Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.62572C>T p.R20858* (on ENST00000591111; = p.R13434* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as rs574660186, CM121827, COSV60149785; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.2794C>T p.Q932* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as rs1567657295, COSV51484518; called by muse, mutect2, varscan2
- AFF2 | c.1862T>C p.V621A | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53994705; called by muse, mutect2, varscan2
- ALKBH5 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67687107; called by muse, mutect2, varscan2
- ARHGAP20 | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV52813821; called by muse, mutect2, varscan2
- C1GALT1C1 | c.771G>T p.E257D | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as COSV58974399; called by muse, mutect2, varscan2
- C6orf118 | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as rs1476979917, COSV57816119; called by muse, varscan2
- CNTLN | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV52083680, COSV99266246; called by muse, mutect2, varscan2
- COL18A1 | c.2490G>T p.K830N (on ENST00000359759 / NM_130444.3; = p.K595N on NM_030582.4) | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV100700925; called by muse, mutect2
- CR1 | c.5156C>T p.P1719L | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV65458393; called by muse, mutect2, varscan2
- DDI2 | c.1171G>T p.A391S | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as COSV60780191; called by muse, mutect2, varscan2
- DDX60L | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs748422357, COSV52710829; called by muse, mutect2, varscan2
- DEFB113 | c.77G>C p.R26T | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV100435342, COSV59038094; called by muse, mutect2, varscan2
- DGKK | c.2780C>G p.P927R | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101053180; called by muse, mutect2
- ERMAP | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as rs747684047, COSV100072367; called by muse, mutect2
- FRMD4A | c.1404G>T p.E468D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.489); catalogued as COSV52727275; called by muse, mutect2, varscan2
- GABRA6 | c.923C>A p.A308D | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251508686, COSV50884225; called by muse, mutect2, varscan2
- GPSM2 | c.1463G>C p.G488A | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV51443160; called by muse, mutect2, varscan2
- GRIN2B | c.3316G>T p.E1106* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | catalogued as rs199799650, COSV74204786, COSV74206480; called by muse, mutect2, varscan2
- H2BW1 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as rs150940915, COSV54221621, COSV99474920; called by muse, mutect2, varscan2
- IL1R1 | c.231C>G p.H77Q | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.011); catalogued as COSV52106663; called by muse, mutect2, varscan2
- IRS4 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV64534247; called by muse, mutect2
- JCAD | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773935496, COSV64760302; called by muse, mutect2, varscan2
- KMT2A | c.6194G>A p.C2065Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100629692; called by muse, mutect2
- LACTB | c.1556T>C p.V519A | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56056278; called by muse, mutect2, varscan2
- LCN10 | c.534C>G p.D178E (on ENST00000474369 / NM_001368089.1; = p.D191E on NM_001001712.3) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100366407, COSV57910806; called by muse, mutect2, varscan2
- LRIG2 | c.2909C>T p.A970V | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV63162747; called by muse, mutect2, varscan2
- MARCHF7 | c.1752G>A p.M584I | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.968); catalogued as COSV99374061; called by muse, mutect2, varscan2
- MKRN3 | c.1301G>C p.G434A | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as COSV58810437; called by muse, mutect2, varscan2
- MLPH | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52819645; called by muse, mutect2, varscan2
- MYO3A | c.3941C>A p.A1314E | Missense Mutation (SNP) | VAF 55/286 reads (19%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV56336140; called by muse, mutect2, varscan2
- NBPF1 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 61/439 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV99844774; called by muse, mutect2, varscan2
- NCAPD3 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.086); catalogued as COSV73258468; called by muse, mutect2, varscan2
- NID2 | c.2945G>A p.W982* | Nonsense Mutation (SNP) | VAF 28/67 reads (42%) | catalogued as COSV99357144; called by muse, mutect2, varscan2
- NOA1 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51737661; called by muse, mutect2, varscan2
- NRP1 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1047454308, COSV55169878; called by muse, mutect2, varscan2
- NXPE1 | c.808G>T p.D270Y (on ENST00000424269; = p.D128Y on NM_152315.5) | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as rs774850877, COSV52630495; called by muse, mutect2, varscan2
- ODF2 | c.1397A>T p.N466I (on ENST00000434106 / NM_153433.2; = p.N442I on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.465); catalogued as COSV63547722; called by muse, mutect2, varscan2
- PEX19 | c.526C>G p.Q176E | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.83); catalogued as rs1480182464, COSV100926977; called by muse, mutect2
- PGAP3 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs760427744, COSV56130547, COSV56131641; called by muse, mutect2, varscan2
- PKIG | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs774154545, COSV63069022; called by muse, mutect2, varscan2
- POLG | c.1488G>T p.K496N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV51522595; called by muse, mutect2, varscan2
- POU3F4 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV64539744; called by muse, mutect2, varscan2
- PYHIN1 | c.865G>T p.V289L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63722928; called by muse, mutect2, varscan2
- SAXO1 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757154901, COSV65869969; called by muse, mutect2
- SBF2 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.049); catalogued as rs954771068, COSV56298365; called by muse, mutect2, varscan2
- SH3TC1 | c.1142A>C p.E381A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV55285973; called by mutect2, varscan2
- SLC25A2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1554296137, COSV53404197; called by muse, mutect2, varscan2
- SLCO2B1 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.248); catalogued as COSV56936285; called by muse, mutect2, varscan2
- SPTA1 | c.6868C>A p.R2290S | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs553043635, COSV63755447, COSV63758486; called by muse, mutect2, varscan2
- SRPX | c.1089+1G>C p.X363_splice | Splice Site (SNP) | VAF 14/122 reads (11%) | catalogued as COSV59439509; called by muse, mutect2, varscan2
- SSX3 | c.184+2T>A p.X62_splice | Splice Site (SNP) | VAF 57/684 reads (8%) | catalogued as COSV100035466; called by muse, mutect2
- SUFU | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.983); catalogued as COSV64015189; called by muse, mutect2, varscan2
- TFAP4 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as rs1245402418, COSV99200096; called by muse, mutect2
- TNXB | c.1121C>G p.P374R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100926578; called by muse, mutect2, varscan2
- TRIM28 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs759243122, COSV53400806; called by mutect2, varscan2
- TTC37 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs148576007; called by muse, mutect2, varscan2
- TTN | c.93827C>T p.S31276F (on ENST00000591111; = p.S23852F on NM_003319.4) | Missense Mutation (SNP) | VAF 65/195 reads (33%) | PolyPhen probably damaging (0.974); catalogued as rs561932256, COSV60149763; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUB | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59491000; called by muse, mutect2, varscan2
- UCP1 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs149333659; called by muse, mutect2, varscan2
- UTRN | c.8603A>C p.K2868T | Missense Mutation (SNP) | VAF 97/236 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62310242; called by muse, mutect2, varscan2
- GATA3 | c.1289_1290del p.F430Wfs*76 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- RNF111 | c.1916_1919del p.L639Hfs*14 | Frame Shift Del (DEL) | VAF 27/123 reads (22%) | called by mutect2, pindel, varscan2
- RNF123 | c.586del p.D196Tfs*3 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, pindel, varscan2
- BEND3 | c.1851C>T p.Y617= | Silent (SNP) | VAF 2/15 reads (13%) | catalogued as rs539619252; called by muse, mutect2
- CA1 | c.657C>T p.V219= | Silent (SNP) | VAF 59/276 reads (21%) | catalogued as COSV56279043; called by muse, mutect2, varscan2
- CLIP1 | c.948C>T p.L316= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV56803723; called by muse, mutect2, varscan2
- CREB5 | c.180G>A p.P60= (on ENST00000357727 / NM_182898.4; = p.P53= on NM_004904.3) | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs765698094, COSV63222917; called by muse, mutect2, varscan2
- EAPP | c.294G>A p.P98= | Silent (SNP) | VAF 65/266 reads (24%) | catalogued as rs770696943, COSV51652132; called by muse, mutect2, varscan2
- EGR4 | c.1347G>A p.P449= (on ENST00000545030; = p.P346= on NM_001965.4) | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs779127293, COSV71532120; called by muse, mutect2, varscan2
- FAT1 | c.3186C>T p.D1062= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs371791429; called by muse, mutect2, varscan2
- KIAA0825 | c.423C>T p.L141= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs778514323, COSV56954397; called by muse, mutect2, varscan2
- KIF21B | c.2802C>G p.V934= | Silent (SNP) | VAF 72/97 reads (74%) | catalogued as COSV59760163; called by muse, mutect2, varscan2
- KIF21B | c.2640C>T p.F880= | Silent (SNP) | VAF 48/83 reads (58%) | catalogued as COSV59760179; called by muse, mutect2, varscan2
- OR6N1 | c.747C>T p.L249= | Silent (SNP) | VAF 112/314 reads (36%) | catalogued as COSV58649134; called by muse, mutect2, varscan2
- PCDHA1 | c.450G>A p.S150= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV65374300; called by muse, mutect2, varscan2
- PGBD1 | c.990C>T p.S330= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as rs866708235, COSV99460830; called by muse, mutect2
- RGS14 | c.376C>T p.L126= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV68771530; called by muse, mutect2, varscan2
- RPIA | c.477C>T p.I159= | Silent (SNP) | VAF 83/328 reads (25%) | catalogued as rs749368086, COSV52170259; called by muse, mutect2, varscan2
- SPACA3 | c.498C>T p.C166= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as COSV99284279; called by muse, mutect2
- SPTBN4 | c.1311G>A p.K437= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1454729413, COSV58952772; called by muse, mutect2, varscan2
- SYNPO2 | c.168C>T p.I56= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV61110302; called by muse, mutect2, varscan2
- ZBBX | c.189C>T p.S63= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs528713569, COSV56792870; called by muse, mutect2, varscan2
- ZFP28 | c.2523A>G p.T841= | Silent (SNP) | VAF 76/153 reads (50%) | catalogued as rs768171743, COSV56736498; called by muse, mutect2, varscan2
- ZNF536 | c.3902G>A p.*1301= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV62826904; called by muse, mutect2, varscan2
- CPLANE1 | c.*5345_*5347del | 3'UTR (DEL) | VAF 50/211 reads (24%) | catalogued as rs772774110; called by pindel, varscan2
- RAB8B | c.*2G>A | 3'UTR (SNP) | VAF 45/159 reads (28%) | catalogued as COSV100369046; called by muse, mutect2, varscan2
- TRIM6 | c.-46C>G | 5'UTR (SNP) | VAF 19/75 reads (25%) | catalogued as COSV53476932; called by muse, mutect2, varscan2
